Gene-level copy-number profile of tumor specimen TCGA-56-A4BX-01A from TCGA case TCGA-56-A4BX, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.5 years (25,745 days).
Specimen TCGA-56-A4BX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3e4031b8-d4e0-4bba-8896-5b788fd9e3af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-A4BX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/12ac72ed-1599-453d-a8bf-30c1a6ab189d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,067; copy number 2: 16,977; copy number 3: 15,301; copy number 4: 15,044; copy number 5: 4,942; copy number 6: 2,452; copy number 7: 818; copy number 8: 94; copy number 10: 11; copy number 11: 421; copy number 12: 220; copy number 15: 40; copy number 17: 15; copy number 19: 118; copy number 20: 4; copy number 25: 147; copy number 27: 21; copy number 28: 122.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-56-A4BX-01): tumor purity 0.87, ploidy 3, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,425 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:31,290,762–35,725,142, 61 genes, copy number 5 (broad region; genes not listed).
- chr2:81,461,358–83,657,842, 20 genes, copy number 5: LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P.
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 4–5): AC244205.1.
- chr2:88,857,161–123,444,445, 702 genes, copy number 5–7 (broad region; genes not listed).
- chr3:158,105,855–198,222,513, 707 genes, copy number 6–28 (within-gene range 3–28) (broad region; genes not listed).
- chr5:58,198–4,440,259, 96 genes, copy number 5–6 (broad region; genes not listed).
- chr5:6,839,460–7,219,291, 1 gene, copy number 5 (within-gene range 4–5): LINC02196.
- chr5:7,047,227–45,895,970, 572 genes, copy number 5–6 (broad region; genes not listed).
- chr7:48,035,511–108,721,601, 1,178 genes, copy number 5–6 (broad region; genes not listed).
- chr7:113,876,777–115,126,314, 9 genes, copy number 5 (within-gene range 4–5): PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393.
- chr7:143,183,419–145,584,817, 80 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–7 (broad region; genes not listed).
- chr10:44,712–43,901,004, 736 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr11:64,778,954–77,637,794, 544 genes, copy number 5 (broad region; genes not listed).
- chr11:77,691,650–77,691,751, 1 gene, copy number 5: Y_RNA.
- chr13:37,481,467–45,083,125, 131 genes, copy number 6–10 (broad region; genes not listed).
- chr13:45,123,093–45,124,143, 2 genes, copy number 6: RN7SKP4, AL138693.1.
- chr13:61,199,798–64,076,044, 29 genes, copy number 5: MIR3169, PCDH20, AL592490.1, LINC02339, RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448, AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1.
- chr13:66,218,250–68,037,131, 17 genes, copy number 5: MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1.
- chr13:76,552,807–114,337,626, 490 genes, copy number 5–6 (broad region; genes not listed).
- chr16:9,068,554–11,797,258, 73 genes, copy number 6 (broad region; genes not listed).
- chr16:28,097,976–35,912,516, 496 genes, copy number 5 (broad region; genes not listed).
- chr17:26,981,694–28,347,009, 60 genes, copy number 7: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3, AC090287.1, AC090287.2, SNORA70, NLK, Vault, RPS29P22, AC061975.8, AC061975.7, PYY2, ERVE-1, AC061975.6, PPY2P, AC061975.2, AC061975.4, AC061975.1, AC061975.5, AC061975.3, KRT18P55, TMEM97, IFT20, TNFAIP1.
- chr17:68,793,549–71,871,750, 37 genes, copy number 5: AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1.
- chr18:5,721,812–15,330,282, 259 genes, copy number 6–10 (broad region; genes not listed).
- chr18:29,629,842–31,426,988, 17 genes, copy number 5 (within-gene range 4–5): AC117569.2, AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA.
- chr19:94,062–19,358,754, 1,070 genes, copy number 5 (broad region; genes not listed).
- chr19:19,401,979–19,402,603, 1 gene, copy number 5: AC092067.1.
- chr19:27,638,483–40,808,434, 501 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
